Somatic mutation profile of tumor specimen TCGA-BT-A20R-01A (aliquot TCGA-BT-A20R-01A-12D-A16O-08) from TCGA case TCGA-BT-A20R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.4 years (28,987 days).
Specimen TCGA-BT-A20R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc0e1c51-4d29-4c79-9d08-90854fa2f78c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20R-11A (Solid Tissue Normal), aliquot TCGA-BT-A20R-11A-11D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/945634e7-475e-4025-bb26-1e7406944ce0

The open-access MAF lists 287 somatic variants for this specimen: 209 protein-altering or splice-affecting, 73 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 73, Nonsense Mutation 19, Frame Shift Del 3, Splice Site 2, In Frame Ins 1, 3'UTR 1, 5'Flank 1, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABRA | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs148182297, COSV61733215; called by muse, mutect2
- ADAM23 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV52224855, COSV52229021; called by muse, mutect2, varscan2
- ADAMTS3 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as COSV54398397, COSV54402472; called by muse, mutect2, varscan2
- ADCY2 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV57869315, COSV57890301; called by muse, mutect2, varscan2
- ADGRF1 | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV51947010; called by muse, mutect2, varscan2
- AIMP2 | c.324G>C p.L108F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1447045312, COSV56151640; called by muse, mutect2, varscan2
- ANK2 | c.5615C>T p.S1872L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs775953030, COSV52144649, COSV52150813; called by muse, mutect2, varscan2
- ANKRA2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as COSV57140510; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100628610; called by mutect2, varscan2
- ANO9 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1383368850, COSV60450899; called by muse, mutect2, varscan2
- APBB1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs543265186, COSV54979012; called by muse, mutect2, varscan2
- ARHGAP27 | c.2235del p.Y746Ifs*26 (on ENST00000428638 / NM_001282290.1; = p.Y405Ifs*26 on NM_199282.3) | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as COSV100976625, COSV65358399; called by mutect2, pindel, varscan2
- ARHGAP29 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs772383920, COSV53109773; called by muse, mutect2, varscan2
- ARID1A | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV61370777; called by muse, mutect2, varscan2
- ASAP2 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV55636477; called by muse, mutect2, varscan2
- ASB13 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV63091809; called by muse, mutect2, varscan2
- ASB16 | c.1297C>G p.R433G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV53235912; called by muse, mutect2, varscan2
- ASXL3 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV52461645, COSV52474635; called by muse, mutect2
- ATP5MF-PTCD1 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV52855346; called by muse, mutect2, varscan2
- AXIN1 | c.2430C>G p.F810L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230408826, COSV51991114; called by muse, mutect2, varscan2
- BMPR2 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV65812376; called by muse, mutect2, varscan2
- BRF1 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV59272185; called by muse, mutect2, varscan2
- C2orf16 | c.2130G>C p.Q710H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs777549367, COSV62677434; called by muse, mutect2, varscan2
- C6orf15 | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99457114; called by muse, mutect2
- CAB39 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs761280518, COSV51477192; called by muse, mutect2, varscan2
- CACNA1C | c.6145G>A p.E2049K (on ENST00000399634 / NM_001167625.1; = p.E1978K on NM_000719.7) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs765320988, COSV59754683; called by muse, mutect2, varscan2
- CACNG5 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV50057807; called by muse, mutect2, varscan2
- CARD9 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53736191; called by muse, mutect2, varscan2
- CATSPERD | c.1702C>G p.Q568E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58466632; called by muse, mutect2, varscan2
- CAVIN2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58424337; called by muse, mutect2, varscan2
- CAVIN4 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs755935790, COSV56867244; called by muse, mutect2, varscan2
- CD68 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs533214352, COSV51511788; called by muse, mutect2, varscan2
- CD7 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53940333; called by muse, mutect2, varscan2
- CDH16 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.076); catalogued as rs766472750, COSV55338673; called by muse, mutect2, varscan2
- CDH7 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1301991832, COSV59891331; called by muse, mutect2, varscan2
- CDIP1 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as COSV54859489, COSV54861231; called by muse, mutect2, varscan2
- CELSR3 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1223302859, COSV51024891; called by muse, mutect2, varscan2
- CEP162 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs201597217, COSV57622675; called by muse, mutect2, varscan2
- CFAP299 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV63884038; called by muse, mutect2, varscan2
- CFH | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV66406049, COSV66411551; called by muse, mutect2, varscan2
- CHAC2 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV54858510, COSV99712690; called by muse, mutect2, varscan2
- CHMP2A | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53397895; called by muse, mutect2, varscan2
- CLCN1 | c.1656G>C p.Q552H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58370925, COSV58373008; called by muse, mutect2, varscan2
- CNST | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1348989449, COSV63620918; called by muse, mutect2, varscan2
- CNTNAP5 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70502347; called by muse, mutect2
- COL6A3 | c.6665G>C p.G2222A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55091390, COSV55102065; called by muse, mutect2, varscan2
- CPD | c.1539G>C p.L513F | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56712231, COSV56715041; called by muse, mutect2, varscan2
- CRYGB | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV53680341, COSV53680491; called by muse, mutect2, varscan2
- CYP26A1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs917140904, COSV56418089, COSV56419463; called by muse, mutect2, varscan2
- DMXL2 | c.7396C>G p.L2466V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV51852349, COSV99198752; called by muse, mutect2, varscan2
- DNAH11 | c.1120C>G p.H374D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV60971903; called by muse, mutect2, varscan2
- DNAH7 | c.10138C>G p.Q3380E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.1); catalogued as COSV56777928; called by muse, mutect2, varscan2
- DNAH8 | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs960637197, COSV59425022; called by muse, mutect2
- DNAJC17 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55026025; called by muse, mutect2, varscan2
- DNAJC30 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV56095913; called by muse, mutect2, varscan2
- DPM1 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV54866536, COSV54867415; called by muse, mutect2, varscan2
- DSP | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65794496; called by muse, mutect2
- DZANK1 | c.1700C>G p.S567C (on ENST00000262547 / NM_001099407.1; = p.S374C on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV52755298; called by muse, mutect2, varscan2
- EFTUD2 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68184241; called by muse, mutect2
- EIF3A | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.156); catalogued as COSV60775567; called by muse, mutect2, varscan2
- EMSY | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.13); catalogued as COSV58264288; called by muse, mutect2, varscan2
- EYA4 | c.1452G>A p.M484I (on ENST00000531901 / NM_001301013.1; = p.M478I on NM_004100.5) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV62058191; called by muse, mutect2, varscan2
- F2RL3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs147915788; called by muse, mutect2, varscan2
- FAF2 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56132491; called by muse, mutect2, varscan2
- FAM160A2 | c.2803C>G p.L935V (on ENST00000449352 / NM_001098794.2; = p.L949V on NM_032127.4) | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV56413645; called by muse, mutect2, varscan2
- FAM47C | c.2617G>C p.D873H | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63729180, COSV63729502; called by muse, mutect2
- FANCD2OS | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.654); catalogued as COSV55037362, COSV55043748; called by muse, mutect2, varscan2
- FANCF | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV59417175; called by muse, mutect2, varscan2
- FAT2 | c.5111C>G p.S1704C | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV55826344; called by muse, mutect2, varscan2
- FAT3 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs748097452, COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FBXO43 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV71054712, COSV71055098; called by muse, mutect2, varscan2
- FGF6 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.206); catalogued as rs532205756, COSV57403538; called by muse, mutect2, varscan2
- FRMD8 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs970834704; called by muse, mutect2
- GANC | c.2012G>C p.R671T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | PolyPhen benign (0.309); catalogued as COSV100531125, COSV58810887; called by muse, mutect2, varscan2
- GDPD2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs910630290, COSV65533888; called by muse, mutect2, varscan2
- GGA1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs766943371, COSV57331253; called by muse, mutect2, varscan2
- GGT6 | c.839G>A p.G280E (on ENST00000574154 / NM_001122890.3; = p.G248E on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54601510; called by muse, mutect2, varscan2
- GOLGA1 | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV65230674; called by muse, mutect2, varscan2
- HECW2 | c.3145G>T p.D1049Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752907605, COSV53669452; called by muse, mutect2, varscan2
- HERC1 | c.11929G>C p.D3977H | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71249507; called by muse, mutect2
- HOXA1 | c.522_528del p.T175Ifs*32 | Frame Shift Del (DEL) | VAF 49/166 reads (30%) | catalogued as COSV56067371; called by mutect2, pindel, varscan2
- IGKV1-5 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs367799323; called by muse, mutect2, varscan2
- IL12RB2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV52025959; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV61143968, COSV61172298; called by muse, mutect2
- INO80 | c.4523C>T p.S1508L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV62741112; called by muse, mutect2, varscan2
- ISOC1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV51492549; called by muse, mutect2, varscan2
- JADE3 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV54468970; called by muse, mutect2, varscan2
- KALRN | c.3683G>C p.G1228A | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV53775245; called by muse, mutect2, varscan2
- KCNC4 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as rs974680413, COSV63925446, COSV63926315; called by muse, mutect2, varscan2
- KCNU1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV101299174, COSV67758684; called by muse, mutect2
- LAMA4 | c.1915G>A p.E639K (on ENST00000230538 / NM_001105206.3; = p.E632K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV57898871; called by muse, mutect2, varscan2
- LBHD1 | c.475G>C p.E159Q (on ENST00000431002 / NM_001367940.1; = p.E133Q on NM_024099.3) | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV63473373; called by muse, mutect2
- LCE3A | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59550914; called by muse, mutect2, varscan2
- LINGO4 | c.1779C>G p.F593L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV64314073; called by muse, mutect2, varscan2
- LMO4 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1028733864, COSV65170510; called by muse, mutect2, varscan2
- LMOD1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66173486, COSV66173517; called by muse, mutect2, varscan2
- LRP1 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.953); catalogued as rs755987592, COSV54525611; called by muse, mutect2
- LRRC3 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as COSV52399339, COSV52399918; called by muse, mutect2, varscan2
- LRRC71 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1455244310; called by muse, mutect2, varscan2
- LYSMD2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51056841, COSV51057014; called by muse, mutect2, varscan2
- MED12 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs769202858, COSV61329448, COSV61343870, COSV61349385; called by muse, mutect2, varscan2
- MED23 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV63435543; called by muse, varscan2
- MINDY2 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs1029819457, COSV57507928; called by muse, mutect2
- MORN3 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV62507715; called by muse, mutect2, varscan2
- MRPL34 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409547839; called by muse, mutect2
- MTOR | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs566273004, COSV63872258, COSV63875955; called by muse, mutect2, varscan2
- MYH13 | c.5445G>T p.Q1815H | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52837771; called by muse, mutect2
- NAP1L1 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV53875717; called by muse, mutect2, varscan2
- NARS1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56877831; called by muse, mutect2, varscan2
- NBR1 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1011818515; called by muse, mutect2
- NES | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV63961008; called by muse, mutect2, varscan2
- NLRC5 | c.1132C>A p.H378N | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs761237528, COSV52660477; called by muse, mutect2, varscan2
- NRP1 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55174228; called by muse, mutect2, varscan2
- NTN4 | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV59222530; called by muse, mutect2, varscan2
- NTRK3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs772244244, COSV62306052; called by muse, mutect2, varscan2
- NUDT13 | c.84-2A>C p.X28_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61969679; called by mutect2, varscan2
- OAZ1 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59233456; called by muse, mutect2, varscan2
- OR1J2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); catalogued as COSV58944893; called by muse, mutect2, varscan2
- OR2L8 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs1384457411, COSV100594357, COSV61727736; called by muse, mutect2, varscan2
- OR4L1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV59850776; called by muse, mutect2, varscan2
- OSBP2 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763399836, COSV60246606; called by muse, mutect2, varscan2
- PCDH12 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343525722, COSV51519819; called by muse, mutect2, varscan2
- PCDH15 | c.5626C>G p.Q1876E | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV57365439; called by muse, mutect2, varscan2
- PCDHGC4 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV52762229; called by muse, mutect2
- PCLO | c.13297G>C p.E4433Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61655791; called by muse, mutect2, varscan2
- PGM2 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV67938732, COSV67939346; called by muse, mutect2, varscan2
- PHLDA3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66210854; called by muse, mutect2, varscan2
- PLEKHH2 | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56754852; called by muse, mutect2
- PNMA5 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs200533836, COSV62626064; called by muse, mutect2, varscan2
- POLA2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485152; called by muse, mutect2
- POLQ | c.3692C>G p.S1231* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | catalogued as COSV51759577; called by muse, mutect2, varscan2
- PPP1R3A | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261031723, COSV52889501; called by muse, mutect2, varscan2
- PPP2R3A | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV53868601; called by muse, mutect2, varscan2
- PPP3R2 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62456796, COSV62457988; called by muse, mutect2, varscan2
- PRAG1 | c.4201A>T p.K1401* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100422579; called by muse, mutect2, varscan2
- PRDM9 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as rs879146332; called by muse, mutect2, varscan2
- PTCHD1 | c.2559G>C p.K853N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV65062093; called by muse, mutect2, varscan2
- PTPN21 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.014); catalogued as COSV60850770; called by muse, mutect2, varscan2
- PTPRC | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV61417007; called by muse, mutect2
- PZP | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.139); catalogued as COSV104432743, COSV54367253, COSV99736611; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2917G>C p.D973H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54762704; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.756); catalogued as rs1212127764, COSV54762713; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV54762724; called by muse, mutect2, varscan2
- RAD51 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1428987216, COSV51111007, COSV51112946; called by muse, mutect2, varscan2
- RAD51AP2 | c.2760G>C p.K920N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101208428, COSV67588061, COSV67588751; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RB1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV57299669; called by muse, mutect2, varscan2
- RBM26 | c.1301A>G p.N434S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57398081; called by muse, mutect2, varscan2
- RBMX2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV59729153; called by muse, mutect2
- RELN | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1554402135, COSV59024630; ClinVar: uncertain significance; called by muse, mutect2
- RFPL1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV62978371; called by muse, varscan2
- RIN1 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1331404898, COSV60928140; called by muse, mutect2, varscan2
- RNF17 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.145); catalogued as COSV55047318; called by muse, mutect2, varscan2
- ROCK1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV67698155; called by muse, mutect2, varscan2
- S100A9 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV64199826; called by muse, mutect2, varscan2
- S1PR1 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59514077; called by muse, mutect2, varscan2
- SCAI | c.1523G>A p.R508Q (on ENST00000336505 / NM_001144877.3; = p.R531Q on NM_173690.5) | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.489); catalogued as rs1037274982, COSV57176079, COSV57176202; called by muse, mutect2, varscan2
- SCFD2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66375566; called by muse, mutect2, varscan2
- SETD2 | c.3755C>T p.S1252L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV57434663, COSV57440663, COSV57446344; called by muse, mutect2, varscan2
- SLC22A12 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs747810130, COSV60573074; called by muse, mutect2, varscan2
- SLC25A47 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs747099355, COSV59925049; called by muse, mutect2, varscan2
- SLC30A6 | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV50873687; called by mutect2, varscan2
- SLC7A2 | c.323G>C p.G108A (on ENST00000494857 / NM_001370338.1; = p.G148A on NM_003046.6) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50265669; called by muse, mutect2, varscan2
- SMYD3 | c.975C>G p.I325M (on ENST00000490107 / NM_001375962.1; = p.I266M on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV63628713; called by muse, mutect2
- SNRNP48 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60939383, COSV60940397; called by muse, mutect2, varscan2
- SOGA3 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as COSV64108020; called by muse, mutect2
- SP100 | c.2352G>C p.L784F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60843168, COSV60848977; called by muse, mutect2, varscan2
- SPECC1L | c.2765C>A p.S922* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100062495; called by muse, mutect2, varscan2
- SPN | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.218); catalogued as COSV64070893; called by mutect2, varscan2
- SPTAN1 | c.6331G>A p.E2111K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63989042, COSV63989612, COSV63990521; called by muse, mutect2, varscan2
- STAB1 | c.5874C>A p.S1958R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV58738625, COSV58741029; called by muse, mutect2, varscan2
- STAT1 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV63117131; called by muse, mutect2, varscan2
- STK16 | c.510G>C p.M170I | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV50280426; called by muse, mutect2, varscan2
- STRADA | c.469G>C p.D157H (on ENST00000336174 / NM_001363786.1; = p.D120H on NM_153335.6) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV55561744, COSV55563930; called by muse, mutect2, varscan2
- TENM2 | c.3172G>A p.E1058K (on ENST00000518659 / NM_001122679.2; = p.E826K on NM_001080428.3) | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1318801022, COSV69137697; called by muse, mutect2, varscan2
- TENM2 | c.5971G>A p.E1991K (on ENST00000518659 / NM_001122679.2; = p.E1752K on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69137700; called by muse, mutect2, varscan2
- TES | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64043252; called by muse, mutect2, varscan2
- TEX14 | c.958G>C p.E320Q (on ENST00000240361 / NM_001201457.2; = p.E314Q on NM_031272.5) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV53623504; called by muse, mutect2, varscan2
- TLN2 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV60893527; called by muse, mutect2, varscan2
- TMEM50A | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.597); catalogued as COSV65486923; called by muse, mutect2, varscan2
- TNNT1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52571479; called by muse, mutect2
- TP53 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52666570, COSV52937236, COSV53050140; called by muse, mutect2, varscan2
- TRANK1 | c.6693G>C p.K2231N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1226670571, COSV57159769; called by muse, mutect2, varscan2
- TTC9 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV56448866, COSV56448905; called by muse, mutect2, varscan2
- TTLL7 | c.853C>G p.Q285E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV53087459; called by muse, mutect2
- TTN | c.87697G>A p.E29233K (on ENST00000591111; = p.E21809K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | PolyPhen benign (0.164); catalogued as COSV60243703; called by muse, mutect2, varscan2
- TTN | c.36176T>C p.V12059A (on ENST00000591111; = p.V4635A on NM_003319.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | PolyPhen benign (0.082); catalogued as rs1438452689, COSV60243717; called by muse, mutect2
- UTP20 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55382852; called by muse, mutect2, varscan2
- VGLL4 | c.64+1del p.X22_splice | Splice Site (DEL) | VAF 11/29 reads (38%) | catalogued as rs1270779554, COSV56080389, COSV99810201; called by mutect2, pindel, varscan2
- ZFP36L1 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100322823; called by muse, mutect2, varscan2
- ZNF574 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55905872; called by muse, mutect2
- ZNF91 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.873); catalogued as COSV56089970; called by muse, varscan2
- ZNF91 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.76); catalogued as COSV56086169, COSV56089993; called by muse, varscan2
- ZWINT | c.711T>A p.D237E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59186110; called by muse, mutect2, varscan2
- BMI1 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- CELSR1 | c.3404C>G p.S1135* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- CORO1A | c.1092C>A p.Y364* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- DAW1 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EIPR1 | c.674_676dup p.N225_A226insD | In Frame Ins (INS) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- IBTK | c.3697G>C p.E1233Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- MAD1L1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- PHF3 | c.4357C>T p.Q1453* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- RFTN2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, varscan2
- SPAG17 | c.925_935del p.E309Lfs*2 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- STARD10 | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- TBC1D1 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 37/170 reads (22%) | called by muse, mutect2, varscan2
- UNC119 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ABCA8 | c.4101G>A p.L1367= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV52208620; called by muse, mutect2, varscan2
- AC127029.3 | c.636C>T p.L212= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV60111665; called by muse, mutect2, varscan2
- ADAM23 | c.303C>T p.I101= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV52224814; called by muse, mutect2
- ADGRF1 | c.1323C>T p.L441= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV51947030; called by muse, mutect2, varscan2
- AJM1 | c.2217C>T p.I739= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs887167830, COSV56034445, COSV56034782; called by muse, varscan2
- ASB18 | c.1227G>A p.P409= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs201896139; called by muse, mutect2, varscan2
- BTN3A1 | c.483G>T p.G161= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV50025216; called by muse, mutect2
- C2orf78 | c.2505C>T p.L835= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV68517202, COSV68518743; called by muse, mutect2, varscan2
- CENPF | c.2883C>T p.I961= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV65277601; called by muse, mutect2, varscan2
- CLK3 | c.603C>T p.D201= (on ENST00000395066 / NM_001130028.1; = p.D53= on NM_003992.4) | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV61414280; called by muse, varscan2
- CLUH | c.477G>C p.L159= (on ENST00000435359; = p.L197= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV70929717; called by muse, mutect2, varscan2
- CRB1 | c.3915G>T p.P1305= | Silent (SNP) | VAF 42/224 reads (19%) | catalogued as COSV66328593; called by muse, mutect2, varscan2
- DHRS9 | c.423C>T p.L141= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV59140860; called by muse, mutect2, varscan2
- DHX33 | c.630G>A p.V210= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV56580337; called by muse, mutect2, varscan2
- DRD5 | c.1200C>T p.I400= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs866493427, COSV58580341, COSV58580483; called by muse, mutect2
- EDC3 | c.1116C>G p.V372= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV59341246; called by muse, mutect2, varscan2
- ESYT1 | c.2214C>A p.L738= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV57271380, COSV57275406; called by muse, mutect2, varscan2
- FOXO4 | c.1236C>A p.V412= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV58576107; called by muse, mutect2, varscan2
- FXR1 | c.1743C>T p.N581= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs760920008, COSV59765118; called by muse, mutect2, varscan2
- GNAO1 | c.822C>G p.L274= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV52618116, COSV99341594; called by muse, mutect2
- GUCA1A | c.240C>A p.L80= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV50004995; called by muse, mutect2, varscan2
- GUCY1A1 | c.1227G>A p.L409= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV56654901; called by muse, mutect2, varscan2
- GUF1 | c.45C>T p.L15= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs772586241, COSV55784184; called by muse, mutect2
- IFNA7 | c.111C>G p.A37= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as rs746250278, COSV53331947; called by muse, mutect2, varscan2
- INHA | c.132C>T p.P44= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs766680434, COSV54719577; called by muse, mutect2
- INPPL1 | c.2523C>G p.L841= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV53358017; called by muse, mutect2, varscan2
- INTS3 | c.705C>T p.F235= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV59680449; called by muse, mutect2
- KALRN | c.1680C>A p.L560= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as COSV53775232; called by muse, varscan2
- KIF1A | c.1482C>G p.L494= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57483127, COSV57497139; called by mutect2, varscan2
- KLB | c.2631G>C p.R877= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV57303847; called by muse, mutect2, varscan2
- KRI1 | c.1188C>T p.L396= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57265470; called by muse, mutect2, varscan2
- LAT | c.282G>A p.T94= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs763554523, COSV57953393; called by muse, mutect2, varscan2
- LINGO4 | c.969G>A p.L323= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV63215803; called by muse, mutect2, varscan2
- MCC | c.2361G>A p.L787= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV56733494; called by muse, mutect2
- MOB2 | c.627C>T p.G209= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs375587388; called by muse, varscan2
- MPP3 | c.357C>T p.L119= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs770143098, COSV68198943; called by muse, mutect2, varscan2
- MRPL52 | c.114C>T p.S38= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs1006032571, COSV61309066; called by muse, mutect2, varscan2
- NRF1 | c.1422G>A p.Q474= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56215114; called by muse, mutect2, varscan2
- OBI1 | c.144T>C p.N48= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV56146670; called by muse, mutect2, varscan2
- OR51F1 | c.636C>T p.L212= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs188896909, COSV58580374; called by muse, mutect2, varscan2
- OR6A2 | c.810C>G p.L270= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV60265532; called by muse, mutect2, varscan2
- PHEX | c.141C>T p.L47= | Silent (SNP) | VAF 43/231 reads (19%) | catalogued as COSV65077727; called by muse, mutect2, varscan2
- PHLPP2 | c.1716C>G p.L572= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1297660963, COSV62426487; called by muse, mutect2
- PKN2 | c.2388G>A p.V796= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV65144061; called by muse, mutect2, varscan2
- PLEKHG4B | c.2808C>T p.P936= (on ENST00000283426; = p.P1292= on NM_052909.5) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs146763332; called by muse, varscan2
- POGLUT2 | c.45T>G p.V15= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57281541; called by muse, mutect2, varscan2
- POLA2 | c.1497C>G p.L499= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV55485179; called by muse, mutect2
- PPFIBP1 | c.2739G>A p.L913= (on ENST00000318304 / NM_177444.3; = p.L907= on NM_003622.4) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs755297298, COSV57287079, COSV57296568, COSV99944445; called by muse, mutect2, varscan2
- PPP2R2C | c.876C>T p.S292= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs751908987, COSV59446450; called by muse, mutect2, varscan2
- PRAG1 | c.4200G>A p.L1400= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58159924; called by muse, mutect2, varscan2
- PTPN23 | c.462C>T p.F154= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs772744440, COSV55546853; called by muse, mutect2, varscan2
- PTPRB | c.2172C>T p.F724= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54249059; called by muse, mutect2, varscan2
- PUM1 | c.2289C>T p.L763= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV57089401; called by muse, mutect2, varscan2
- RASGRF2 | c.786C>T p.L262= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs765887785, COSV54136133; called by muse, mutect2, varscan2
- RUNX1T1 | c.1764G>A p.P588= (on ENST00000265814 / NM_001198628.1; = p.P561= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs144186445; called by muse, mutect2, varscan2
- SIPA1L3 | c.2847G>A p.R949= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1035483541, COSV55914573; called by muse, mutect2
- SLC45A3 | c.294G>A p.L98= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV65655323; called by muse, mutect2, varscan2
- SLC9A4 | c.1551G>C p.V517= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV54837412; called by muse, mutect2, varscan2
- TAS2R16 | c.252C>T p.T84= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV50798254; called by muse, mutect2, varscan2
- TCOF1 | c.2583G>A p.Q861= (on ENST00000377797 / NM_001135243.1; = p.Q784= on NM_000356.4) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1365099283, COSV60352289; called by muse, mutect2, varscan2
- TRPM2 | c.2031G>A p.A677= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs759551247, COSV55974538; called by muse, mutect2, varscan2
- TUBGCP2 | c.1986C>T p.N662= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV53307633; called by muse, mutect2, varscan2
- TWSG1 | c.351C>T p.N117= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs143807731; called by muse, mutect2, varscan2
- UBE4B | c.1635C>G p.L545= (on ENST00000343090 / NM_001105562.3; = p.L416= on NM_006048.5) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV53538634; called by muse, varscan2
- VMP1 | c.1116C>T p.V372= | Silent (SNP) | VAF 35/248 reads (14%) | catalogued as rs111262775, COSV51868729; called by muse, mutect2, varscan2
- WASHC3 | c.123C>T p.L41= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1180139731, COSV53532367; called by muse, mutect2, varscan2
- ZFYVE26 | c.984G>C p.L328= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV61331969; called by muse, mutect2, varscan2
- ZNF146 | c.129T>G p.P43= | Silent (SNP) | VAF 135/211 reads (64%) | catalogued as COSV61932441; called by muse, mutect2, varscan2
- ZNF223 | c.1059C>T p.F353= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as COSV71572021; called by muse, mutect2, varscan2
- ZNF429 | c.828G>A p.K276= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs761289294, COSV61917967; called by mutect2, varscan2
- ZNF45 | c.1983C>G p.V661= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV54194211; called by muse, mutect2
- ZNF587 | c.1605C>T p.L535= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV57150145; called by muse, mutect2, varscan2
- ZNF681 | c.96G>C p.V32= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV68074450, COSV68075177; called by muse, mutect2, varscan2
- BEND6 | chr6:56954597 G>A | 5'Flank (SNP) | VAF 8/38 reads (21%) | catalogued as rs765215402; called by muse, mutect2, varscan2
- MIR7-2 | n.19G>A | RNA (SNP) | VAF 3/15 reads (20%) | catalogued as rs775124726; called by muse, mutect2
- MRNIP | c.*2C>A | 3'UTR (SNP) | VAF 50/271 reads (18%) | catalogued as COSV99481709; called by muse, mutect2, varscan2
- VPS13B | c.4820+15779C>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100662930; called by muse, mutect2
- ZBTB3 | c.-113C>T | 5'UTR (SNP) | VAF 10/76 reads (13%) | catalogued as rs779021393, COSV67361712; called by muse, mutect2, varscan2
